Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7889, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7889-01A (Primary Tumor).

[page 1 of 5]
Ordering: _____

Surgical Pathology Report

Inquiry Number: _____

Accession Number: _____

Collected Date: _____

Pathologist: _____

Received Date/Time: _____

Specimen Description

- A. Gallbladder
- B. Lymph node of importance
- C. Bile duct margin
- D. Pancreatic duct margin
- E. Whipple's specimen

Clinical Information

Pancreatic adenocarcinoma

Diagnosis

A. Gallbladder:

- Chronic cholecystitis.
- Negative for malignancy or dysplasia.
- Cystic duct not involved by carcinoma.

B. Lymph Node of Importance:

- One reactive lymph node, negative for malignancy.

C. Bile Duct Margin:

- Negative for malignancy or dysplasia.

D. Pancreatic Duct Margin:

- Negative for malignancy or dysplasia.

[page 2 of 5]
E. Whipple's Specimen:

- Invasive well differentiated pancreatic ductal carcinoma, 2.5 cm.
- **POSITIVE** for extensive perineural invasion.
- **POSITIVE** for lymphatic invasion.
- Tumor invaded into peripancreatic fat.
- Negative for angiovascular invasion.
- Multifocal pancreatic intraductal neoplasm (PanIN- 1b to 3).
- Resection margins of pancreas negative for tumor: 1.5 mm distant from the posterior margin, and 2.0 mm distant from the resection margin of pancreas.
- Ampulla and duodenal mucosa not involved by tumor.
- Three of thirteen (3/13) peripancreatic lymph nodes **POSITIVE** for metastatic carcinoma.
- *See Synoptic Report.*

Synoptic Report

E: Pancreas (Exocrine), Macroscopic

SPECIMEN:

Head of pancreas

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE:

Greatest dimension: 2.5 cm

[page 3 of 5]
Additional dimensions: 2.2 x 1.7 cm

E: Pancreas (Exocrine), Microscopic

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G1: Well differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades peripancreatic soft tissues

Tumor invades retroperitoneal soft tissue

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 1.5 mm

Specified margin: Posterior

Margins uninvolved by carcinoma in situ

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

No prior treatment

LYMPH-VASCULAR INVASION:

Present

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 13

Number involved: 3

DISTANT METASTASIS (pM):

Not applicable

ADDITIONAL PATHOLOGIC FINDINGS:

Pancreatic intraepithelial neoplasia (highest grade: PanIN 2 and 3)

Gross Description

Received are specimens A to E. All requisitions and specimen containers are labelled with the patient's name

The cassettes and AP identifiers are labelled with the Surgical Number

[page 4 of 5]
[REDACTED]

A. The specimen is received fresh and consists of an entirely resected gallbladder measuring 8.5 in length and 2.9 cm in maximum diameter. On the serosal surface the gallbladder appears unremarkable. Upon opening, no gallstones are present. The cystic mucosa appears unremarkable. The cystic wall is thickened, up to 0.3 cm for the thickness. Representative sections are submitted in one cassette.

[REDACTED]

B. The specimen is received in formalin and consists of one lymph node measuring 1.1 cm in greatest dimension. The lymph node is bisected and submitted in one cassette.

[REDACTED]

C. Circular piece of mucosa 1.0 x 1.0 x 0.3 cm. Bisected and both halves submitted for QS.

[REDACTED]

The entire frozen section block remnant is submitted in cassette CQS1.

[REDACTED]

D. Irregular piece of soft tan tissue, 1 x 0.3 x 0.3 cm. All submitted for QS.

[REDACTED]

The entire frozen section block remnant is submitted in cassette DQS1.

[REDACTED]

E. Received fresh is a Whipple resection specimen encompassing a segment of duodenum, 24 cm in length and 6 cm in maximal circumference, and a portion of pancreas measuring 4.2 x 3.0 x 2.2 cm, and a portion of bile duct is included, 1.8 cm in length and 0.8 cm in proximal diameter. Merged with this bile duct, the pancreatic duct is identified, measuring 1.2 cm in length and 0.8 cm in proximal diameter. After the ducts merged, starting at 1.2 cm from the proximal resection margin of the pancreatic duct, the common ductal lumen is significantly narrowed until 0.2 cm from the opening of the ampulla. Surrounding the common duct is an ill-defined firm mass in the pancreatic head, measuring 2.5 x 2.2 x 1.7 cm. The duodenal mucosa appears unremarkable. The ampulla is not involved by the tumor. The resection margin of the pancreas is inked in blue, the posterior resection margin of the pancreas is inked in black, the luminal surface of the pancreatic duct inked in yellow, the luminal surface of bile duct inked in orange, and the common duct luminal surface is inked in purple. Representative sections are submitted in cassettes labelled as follows:

- E1 - bile duct margin.
- E2-3 - longitudinal sections through common duct and ampullary opening.
- E4-5 - pancreas with posterior margin, next to sections E2 and E3.
- E6-8 - a single cross section of mass with pancreatic resection margin and common duct.
- E9-10 - a single cross section of tumor with both pancreatic and bile duct.
- E11 - longitudinal section through the proximal end of pancreatic duct and the surrounding
- [REDACTED]
- [REDACTED]

[page 5 of 5]
- [REDACTED]
- tumor.
- E12 - longitudinal section of the proximal end of bile duct with surrounding tumor.
- E13 - bisected lymph node next to the proximal bile duct.
- E14 - cross section of tumor with common duct.
- E15-17 - a single cross section of tumor through common duct with pancreatic resection margin.
- E18-22 - a single cross section through the tumor with common bile duct, pancreatic resection margin and duodenum.
- E23-24 - tumor with pancreatic resection margin.
- E25 - uninvolved pancreas with duodenum.
- E26 - distal and proximal resection margins of duodenum.
- E27-28 - additional posterior margin.
- E29 - lymph node within duodenal mesentery.
- E30 - four peripancreatic lymph nodes.
- E31 - four peripancreatic lymph nodes.
- E32 - tumor nodule within the posterior aspect.
- [REDACTED]

Frozen Section Diagnosis

C. Bile Duct Margin:

- Negative for tumor

[REDACTED] [REDACTED]

D. Pancreatic Duct Margin:

- Negative for tumor.

[REDACTED]

Reported by: [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 9b013883-e4a7-4392-9729-820be05d2430 (TCGA-IB-7889.ECA003D0-D6E7-4A93-9944-F4FDF6361F74.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).